Somatic mutation profile of tumor specimen TARGET-10-PARBSP-09A (aliquot TARGET-10-PARBSP-09A-01D) from TARGET case TARGET-10-PARBSP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,259 days).
Specimen TARGET-10-PARBSP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b96b322c-7304-40a3-98bf-3d0743bd514e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBSP-10A (Blood Derived Normal), aliquot TARGET-10-PARBSP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e519c9db-62d8-4172-a99b-41cbd0884311

The open-access MAF lists 15 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, 3'Flank 2, Intron 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf20 | c.1546G>A p.G516R | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs1269769957; called by muse, mutect2
- MRGPRF | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57996013; called by muse, mutect2, varscan2
- SLC22A8 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs766443125, COSV60324647; called by muse, mutect2, varscan2
- CATSPER1 | c.108C>A p.H36Q | Missense Mutation (SNP) | VAF 68/116 reads (59%) | SIFT tolerated (0.24); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CXorf58 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- GLT1D1 | c.958G>A p.V320M (on ENST00000442111 / NM_001366889.1; = p.V240M on NM_144669.3) | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- IGLV4-60 | chr22:22162679 TCAC>CCTCGGGGG | Missense Mutation (INS) | VAF 22/27 reads (81%) | called by pindel, varscan2*
- FCGR3A | c.492C>G p.L164= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV63458904; called by muse, mutect2, varscan2
- OR8B12 | c.354G>A p.A118= | Silent (SNP) | VAF 43/96 reads (45%) | catalogued as rs764768343, COSV60911867; called by muse, mutect2, varscan2
- RORB | c.522G>A p.P174= (on ENST00000396204 / NM_001365023.1; = p.P163= on NM_006914.4) | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as rs774427225; called by muse, mutect2, varscan2
- AC113208.3 | n.2492G>A | RNA (SNP) | VAF 6/21 reads (29%) | catalogued as rs941559102; called by muse, mutect2, varscan2
- COL6A3 | c.7669-152C>A | Intron (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- FUBP3 | c.1583-97C>T | Intron (SNP) | VAF 7/17 reads (41%) | catalogued as rs948919509; called by muse, mutect2
- IGHV3-43 | chr14:106470263 ins CTA | 3'Flank (INS) | VAF 47/48 reads (98%) | called by mutect2, pindel*, varscan2*
- IGKV2D-29 | chr2:89948269 ins CCCCCC | 3'Flank (INS) | VAF 19/30 reads (63%) | called by pindel, varscan2
